Somatic mutation profile of tumor specimen C3L-01603-03 (aliquot CPT0087040009) from CPTAC case C3L-01603, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 63.6 years (23,226 days).
Specimen C3L-01603-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57f97554-75a8-4fc5-bf7a-39ff7969ddd0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01603-31 (Blood Derived Normal), aliquot CPT0087460001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99292300-f3e0-4208-94c3-54a33e356391

The open-access MAF lists 68 somatic variants for this specimen: 48 protein-altering or splice-affecting, 8 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 8, Frame Shift Del 7, Frame Shift Ins 6, Intron 4, 3'UTR 3, RNA 3, 5'UTR 1, In Frame Del 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC127029.3 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 224/892 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs71640273, CM030866; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY4 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 110/456 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs148797686, COSV99353081; called by muse, mutect2, varscan2
- ANKMY1 | c.2666T>C p.V889A | Missense Mutation (SNP) | VAF 80/361 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1199191325, COSV56036094; called by muse, mutect2, varscan2
- BAZ2A | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 32/943 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV51630673; called by muse, mutect2
- F8 | c.1315G>A p.G439S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as CM031983, CM080340; called by muse, mutect2, varscan2
- FCGBP | c.7364C>T p.A2455V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.372); catalogued as rs775584193; called by mutect2, varscan2
- GBA2 | c.967C>T p.L323F | Missense Mutation (SNP) | VAF 120/519 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs769905389; called by muse, mutect2, varscan2
- GRAMD1C | c.1538G>C p.R513T | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV63983693; called by muse, mutect2, varscan2
- HAUS2 | c.353del p.C118Sfs*23 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | catalogued as COSV53000776; called by mutect2, pindel
- JPH2 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 226/788 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs894217949, COSV65905525; called by muse, mutect2, varscan2
- MIIP | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs759958145; called by muse, mutect2, varscan2
- PCDHB12 | c.1109T>C p.I370T | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.353); catalogued as rs1554286790; called by muse, mutect2, varscan2
- RGS18 | c.198del p.H68Tfs*14 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | catalogued as COSV66508042; called by mutect2, pindel
- TRIM36 | c.2120G>A p.G707D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56688694; called by muse, mutect2, varscan2
- ACHE | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 51/224 reads (23%) | called by muse, mutect2, varscan2
- ANKH | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 109/461 reads (24%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- BICC1 | c.757_763del p.I253Efs*10 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel
- BTBD1 | c.583del p.A196Lfs*5 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel
- C11orf53 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 108/410 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CHST1 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 91/371 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CMBL | c.327G>T p.E109D | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CPN2 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 55/275 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- CYP3A5 | c.1278del p.I426Mfs*19 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- DUS4L | c.830G>A p.C277Y | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- EFCAB5 | c.3140_3141insGA p.D1048Kfs*8 | Frame Shift Ins (INS) | VAF 3/27 reads (11%) | called by mutect2, pindel
- ENY2 | c.295dup p.A99Gfs*8 | Frame Shift Ins (INS) | VAF 3/34 reads (9%) | called by mutect2, pindel
- FASTKD5 | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBXW5 | c.616C>A p.L206M | Missense Mutation (SNP) | VAF 102/483 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- FYB2 | c.1801G>A p.D601N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- LEKR1 | c.714del p.R239Dfs*10 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- LRRC8B | c.807dup p.V270Cfs*17 | Frame Shift Ins (INS) | VAF 10/61 reads (16%) | called by mutect2, pindel
- MEX3A | c.353T>A p.L118H | Missense Mutation (SNP) | VAF 111/431 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- MORC2 | c.853A>C p.K285Q (on ENST00000397641 / NM_001303256.3; = p.K223Q on NM_014941.3) | Missense Mutation (SNP) | VAF 65/421 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- OGFR | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 168/1444 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); called by muse, varscan2
- OSGEPL1 | c.732_733insA p.H245Tfs*3 | Frame Shift Ins (INS) | VAF 3/38 reads (8%) | called by mutect2, pindel
- PIK3CA | c.1260_1265del p.C420_L422delinsW | In Frame Del (DEL) | VAF 7/38 reads (18%) | called by mutect2, pindel, varscan2
- PPA1 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- RBFOX1 | c.635del p.N212Ifs*146 | Frame Shift Del (DEL) | VAF 3/37 reads (8%) | called by mutect2, pindel
- SAP30L | c.181A>C p.K61Q | Missense Mutation (SNP) | VAF 94/431 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEC23A | c.2243G>T p.S748I | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, varscan2
- SLC12A7 | c.1268T>C p.L423P | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SPATA31A1 | c.3167G>A p.G1056D | Missense Mutation (SNP) | VAF 124/600 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.164); called by muse, varscan2
- SYNE1 | c.4212_4213insT p.E1405* (on ENST00000367255 / NM_182961.4; = p.E1412* on NM_033071.3) | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | called by mutect2, pindel
- TMEM245 | c.2635G>C p.G879R | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TRAF3IP1 | c.1543_1546dup p.Q516Pfs*5 | Frame Shift Ins (INS) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- UBE3C | c.2380A>G p.T794A | Missense Mutation (SNP) | VAF 75/295 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- UNC5CL | c.472G>C p.G158R | Missense Mutation (SNP) | VAF 129/464 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- WDR61 | c.343T>A p.S115T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- DNAH11 | c.9240G>T p.L3080= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- EYA4 | c.72T>G p.S24= | Silent (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- FGL1 | c.540A>G p.E180= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- GLI2 | c.2859C>T p.S953= (on ENST00000361492 / NM_001374353.1; = p.S970= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 138/513 reads (27%) | catalogued as rs1476081450; called by muse, mutect2, varscan2
- MBTPS1 | c.1353G>T p.R451= | Silent (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- RNF181 | c.15C>T p.F5= | Silent (SNP) | VAF 77/460 reads (17%) | catalogued as rs946189282; called by muse, mutect2, varscan2
- SCNN1B | c.726C>T p.G242= | Silent (SNP) | VAF 188/715 reads (26%) | catalogued as rs148125384; called by muse, mutect2, varscan2
- TNC | c.3984C>T p.G1328= | Silent (SNP) | VAF 103/368 reads (28%) | catalogued as rs554908600, COSV60781212; called by muse, mutect2, varscan2
- AC009053.1 | n.293G>A | RNA (SNP) | VAF 68/1440 reads (5%) | catalogued as rs777641116; called by muse, mutect2
- AL035696.1 | n.291C>A | RNA (SNP) | VAF 121/465 reads (26%) | called by muse, mutect2, varscan2
- C11orf52 | chr11:111929879 T>G | 3'Flank (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- DYRK4 | c.1321+40G>A | Intron (SNP) | VAF 54/214 reads (25%) | catalogued as rs752395363; called by muse, mutect2
- GOLGA4 | c.*21_*22dup | 3'UTR (INS) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- MLC1 | c.*18C>T | 3'UTR (SNP) | VAF 160/664 reads (24%) | catalogued as rs111797969; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MRPL3 | c.-28C>T | 5'UTR (SNP) | VAF 22/470 reads (5%) | catalogued as rs1207942033; called by muse, mutect2
- RNF103 | c.366+2312T>A | Intron (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
- RPL3 | c.688+103G>A | Intron (SNP) | VAF 108/545 reads (20%) | catalogued as rs377149797; called by muse, mutect2, varscan2
- SNORD115-14 | n.13A>G | RNA (SNP) | VAF 84/310 reads (27%) | called by muse, mutect2, varscan2
- SPNS1 | c.*58G>A | 3'UTR (SNP) | VAF 94/437 reads (22%) | catalogued as rs748746757; called by muse, mutect2, varscan2
- ZDHHC20 | c.945-382_945-380del | Intron (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
